CPTAC case C3L-00561 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bf2c7bd9-65d7-41af-84b5-41ffe6693547

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1966; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 50.6 years (18,481 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: G4; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 1,796 days (4.9 years); Progression or recurrence: yes; Days to last follow up: 1,796 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 10 cm (a second GDC size field records 6 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 29; Margin status: Involved; Sarcomatoid present: No.

Follow-up (6 entries)
- Days to follow up: 368 days (1.0 years); Disease response: With Tumor.
- Days to follow up: 708 days (1.9 years); Disease response: With Tumor.
- Days to follow up: 1,044 days (2.9 years); Disease response: With Tumor.
- Days to follow up: 1,432 days (3.9 years); Disease response: With Tumor.
- Days to follow up: 1,796 days (4.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 368 days (1.0 years).
- Days to follow up: 1,796 days (4.9 years); Disease response: With Tumor.

Other clinical attributes
- Weight: 94 kg; Height: 185 cm; BMI: 27.47.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00561-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 426 mg; Time between excision and freezing: 18 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00561-21: Section location: Middle; Percent tumor nuclei: 90; Percent necrosis: 5.
- Sample C3L-00561-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 367 mg.
- Sample C3L-00561-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 330 mg; Time between excision and freezing: 18 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00561-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
